Somatic mutation profile of tumor specimen 0DL8QI from CCDI case PBBZDN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 1.8 years (651 days).
Specimen 0DL8QI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbde27be-48d9-4423-a336-693f04e6298f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL8PY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f025f84-61e9-488f-8e68-c29ae99a9d3e

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 267/638 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.814+6C>T | Splice Region (SNP) | VAF 73/340 reads (21%) | catalogued as rs1012967402; called by muse, mutect2, varscan2
- CCDC87 | c.2424G>T p.K808N | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59579421; called by muse, mutect2
- FOXO4 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 219/568 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs763379588; called by muse, mutect2, varscan2
- MDN1 | c.15031_15033del p.E5011del | In Frame Del (DEL) | VAF 148/414 reads (36%) | catalogued as rs777008224; called by pindel, varscan2
- MXRA5 | c.6367G>A p.V2123M | Missense Mutation (SNP) | VAF 256/612 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779869276, COSV54254220; called by muse, mutect2, varscan2
- VPS13D | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 96/701 reads (14%) | catalogued as rs752359125, COSV62531842; called by muse, mutect2, varscan2
- EDEM3 | c.1295del p.N432Ifs*2 | Frame Shift Del (DEL) | VAF 153/408 reads (38%) | called by mutect2, pindel, varscan2
- HAUS7 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 167/845 reads (20%) | called by muse, mutect2, varscan2
- CRYAB | c.324+19dup | Intron (INS) | VAF 82/212 reads (39%) | catalogued as rs782303631; ClinVar: likely benign; called by mutect2, varscan2
